Surgical pathology report (de-identified scan), TCGA case TCGA-IA-A83V, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Cleveland Clinic, specimen TCGA-IA-A83V-01A (Primary Tumor).

[page 1 of 3]
Results**SURGICAL PATHOLOGY****Patient Info**

Patient Name

Sex
Male

DOB

Results

Physician:

SPECIMEN #:

FINAL DIAGNOSIS:

LEFT KIDNEY AND LEFT ADRENAL GLAND, RADICAL NEPHRECTOMY - RENAL CELL
CARCINOMA, PAPILLARY TYPE, NUCLEAR GRADE II/IV.
- ADRENAL GLAND WITH NO PATHOLOGIC DIAGNOSIS.

Comment: The tumor is present as a 5.0 cm mass arising within the
lower portion of the left kidney. The tumor extends beyond the
normal renal parenchyma into the perirenal adipose tissue. No
extension into renal sinus is seen. The ureteral and renal vascular
margins of excision are negative for neoplasm. No involvement of the
left adrenal gland is seen.

Redacted**** Report Electronically Signed Out ****

SPECIMEN(S) SUBMITTED:

LEFT KIDNEY LEFT ADRENAL GLAND

CLINICAL DATA:

RENAL MASS

*ICD-O-3
Carcinoma, papillary renal cell 8260/3
Site @ Kidney NOS C64.9
J 10/17/13*

GROSS DESCRIPTION:

A. Received is a specimen labeled "left kidney and left adrenal gland". The specimen consists of a left kidney containing a mass and is surrounded by an irregular envelope of fibroadipose tissue. The neoplasm does not appear to extend into the perirenal fat. The specimen weighs 344.50 grams after removing perirenal fat. The specimen is sectioned from superior to inferior. A mass involves the lower portion of the kidney. On section the tumorous mass is roughly spherical and measures 5 x 5 x 4 cm. It is composed of yellow tissue with foci of hemorrhage and softening. The tumor does not invade the pelvocalyceal system or the renal sinus. The tumor is sharply demarcated from the renal parenchyma which appears essentially unremarkable. Satellite nodules of tumor are not present in the renal tissue. Dissection of the renal veins particularly those draining the area of the mass does not show intravascular presence of the neoplasm. The adrenal gland is present and measures 5 x 4 x 0.4 cm and weighs 11.31 grams. It is not involved by the mass. A 5 cm segment of ureter is present and is essentially unremarkable. Representative sections are submitted in formalin with the following designations: #1 ureter and vessels; #2 pelvis; #3 sinus; #4 - #6 tumor in respect to the capsule; #7 tumor; #8 perirenal fat; #9 adrenal gland.

[page 2 of 3]
Patient ID #: [REDACTED]

DOB: [REDACTED]

Physician:

Financial #:

Date of Report:

Date of Procedure:

Date of Receipt:

Location:

Lab and Collection

SURGICAL PATHOLOGY [REDACTED] on

Lab and Collection Information

Result History

SURGICAL PATHOLOGY [REDACTED] on

Order Result History Report

Result Information

Result Date and Time

Status

Provider Status

Final result

Ordered

Status:

This result is currently not released to

Display Full Result Report

Display Order Report

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form 4.05

Study Subject ID:		Person ID:	N/A
Study/Site:	TCGA Kidney renal papillary cell carcinoma - carcinoma)	(Kidney renal papillary cell	Age: N/A
Event:	PathDiscrepancy		Date of Birth:
Interviewer:			Sex: M

Tumor Identifier Provided on Initial Case Quality Control Form

Provide the tumor identifier documented on the initial case quality control form for this case.

Pathologic Diagnosis Provided on Initial Pathology Report

renal cell carcinoma

Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.

Histologic features of the sample provided for TCGA, as reflected on the CQCF

papillary type

Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form

confirmation of clarification of KIRP Type II provided in discrepancy note

Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.

Name of TSS Reviewing Pathologist or Biorepository Director

Provide the name of the pathologist who reviewed this case for TCGA.

Source: NCI Genomic Data Commons file cac8b604-d6bb-439a-815d-c7cceb1690a9 (TCGA-IA-A83V.DD45EC6D-A44D-4B7D-9EBA-1ACDEC258FF5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).